Surgical pathology report (de-identified scan), TCGA case TCGA-XR-A8TC, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University of Sao Paulo, specimen TCGA-XR-A8TC-01A (Primary Tumor).

Nature of material: Liver
Biopsy number:

ANATOMOPATHOLOGIC RESULT

MACROSCOPY

Received 2 vials, identified as follows:

-Nodule in segment I: Product of liver segmentectomy fragmented into two portions, together weighing 13.0 g and measuring 5.5 x 3.5 x 2.2 cm. Presents near the capsule, nodular, whitish, soft and well defined lesion, which measures 1.2 cm in diameter and is 0.9 cm from the surgical resection margin. The adjacent hepatic parenchyma has hard consistency.

-Nodule in segment VIII: Product of liver segmentectomy weighing 28.0 g and measuring 5.5 x 4.0 x 2.5 cm. Presents, to the cuts, nodular lesion, with subcapsular location, which is indurated and well defined. The lesion measures 1.7 cm in diameter and is 0.5 cm from the surgical resection margin. The adjacent hepatic parenchyma has hard consistency.

MICROSCOPY

Dispensable description.

DIAGNOSTIC

Products of liver segmentectomy (segment I and VIII):

- Moderately differentiated hepatocellular carcinoma in both segments received. The lesions have larger diameters of 1.2 cm and 1.7 cm and show solid, trabecular and focally pseudoacinar morphological patterns.
- Presence of macrovesicular steatosis in about 10% of the neoplastic cells.
- Significant necrosis was not detected.
- Absence of vascular or lymphatic invasion in the evaluated cuts.
- Surgical margins free from neoplastic infiltration.
- Hepatic parenchyma adjacent to lesions with mild lymphocytic inflammatory infiltrate in portal spaces and septa, baloniforme degeneration in about 30% of hepatocytes and severe fibrosis, sketching out some regenerative nodules (B virus infection, according to clinical data).
- Absence of significant hemosiderosis to Perls stain.
- Pathological staging: pT2 pNx.

PARTICIPANTS OF APPRAISAL REPORT

- ISSUER

ICD-O-3

Carcinoma, hepatocellular NOS 8170/3

Site: Liver C22.0

JP 1/29/14

Source: NCI Genomic Data Commons file dfdc8d27-0bff-4241-8d16-b00b97d9e43b (TCGA-XR-A8TC.681B14A0-98E6-4F74-89B0-3DFB3A97C0E1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).